Somatic mutation profile of tumor specimen TCGA-AG-3891-01A (aliquot TCGA-AG-3891-01A-01W-1073-09) from TCGA case TCGA-AG-3891, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.8 years (24,411 days).
Specimen TCGA-AG-3891-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ae0aabf-5fe0-468c-8c78-9defda831e3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3891-10A (Blood Derived Normal), aliquot TCGA-AG-3891-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20eeb11f-b56a-4900-a898-4abd486e4f73

The open-access MAF lists 668 somatic variants for this specimen: 518 protein-altering or splice-affecting, 133 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 354, Silent 133, Frame Shift Ins 78, Frame Shift Del 47, Splice Site 16, Nonsense Mutation 13, Intron 7, Splice Region 5, RNA 5, 5'Flank 2, Translation Start Site 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.10131dup p.Q3378Tfs*12 | Frame Shift Ins (INS) | VAF 87/382 reads (23%) | catalogued as rs1553416867; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- APC | c.1102_1103del p.V368Ifs*9 | Frame Shift Del (DEL) | VAF 44/180 reads (24%) | catalogued as rs1554080016; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATM | c.8545C>T p.R2849* | Nonsense Mutation (SNP) | VAF 113/464 reads (24%) | catalogued as rs587778080, CM990221, COSV53771567; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- DGKE | c.610dup p.T204Nfs*4 | Frame Shift Ins (INS) | VAF 13/50 reads (26%) | catalogued as rs147972030; ClinVar: pathogenic; called by mutect2, varscan2
- FSHB | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 19/90 reads (21%) | catalogued as rs374623109, COSV54221612; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ITGB4 | c.600dup p.F201Lfs*15 | Frame Shift Ins (INS) | VAF 24/74 reads (32%) | catalogued as rs752657203; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 24/106 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.1840A>T p.K614* | Nonsense Mutation (SNP) | VAF 73/130 reads (56%) | catalogued as rs63750490, CM083753, COSV56221044; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RPE65 | c.1067del p.N356Mfs*17 | Frame Shift Del (DEL) | VAF 44/198 reads (22%) | catalogued as rs281865520, CD972436; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- TGFB2 | c.821del p.N274Tfs*10 | Frame Shift Del (DEL) | VAF 33/171 reads (19%) | catalogued as rs863223796; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABHD12 | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100194580; called by muse, mutect2, varscan2
- ACOX3 | c.65A>T p.D22V | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV100711986; called by muse, mutect2, varscan2
- ACTB | c.1064T>C p.M355T | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100079738; called by muse, mutect2, varscan2
- ACTB | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.181); catalogued as COSV100079740; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 48/226 reads (21%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM28 | c.2045T>C p.V682A | Missense Mutation (SNP) | VAF 125/338 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99739109; called by muse, mutect2, varscan2
- ADAM30 | c.1013A>G p.H338R | Missense Mutation (SNP) | VAF 108/325 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101023911; called by muse, mutect2, varscan2
- ADGRA2 | c.2020G>A p.V674M | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs772222895, COSV59441378; called by muse, mutect2
- ADGRB1 | c.1318dup p.Q440Pfs*8 | Frame Shift Ins (INS) | VAF 8/19 reads (42%) | catalogued as rs772974645; called by mutect2, varscan2
- ADGRE2 | c.2167A>G p.T723A | Missense Mutation (SNP) | VAF 76/312 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV59692952; called by muse, varscan2
- ADGRE3 | c.762del p.F254Lfs*12 | Frame Shift Del (DEL) | VAF 64/293 reads (22%) | catalogued as rs762974450; called by mutect2, varscan2
- ADGRF1 | c.1567dup p.S523Ffs*32 | Frame Shift Ins (INS) | VAF 52/176 reads (30%) | catalogued as rs987850677; called by mutect2, varscan2
- ADRA1A | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.585); catalogued as COSV99371372; called by muse, mutect2, varscan2
- AMBN | c.1337A>G p.E446G | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59825883; called by muse, mutect2, varscan2
- AMOTL1 | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 67/251 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.312); catalogued as COSV58566021; called by muse, mutect2, varscan2
- ANAPC4 | c.1891G>C p.V631L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100194138; called by muse, mutect2, varscan2
- ANAPC5 | c.336dup p.D113* | Frame Shift Ins (INS) | VAF 26/126 reads (21%) | catalogued as rs782081656; called by pindel, varscan2
- ANK3 | c.12200A>G p.K4067R | Missense Mutation (SNP) | VAF 77/323 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.985); catalogued as COSV99780730; called by muse, mutect2, varscan2
- ANK3 | c.3742A>G p.I1248V (on ENST00000280772 / NM_001320874.2; = p.I382V on NM_001149.3) | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV99780734; called by muse, mutect2, varscan2
- ANXA13 | c.832-1G>A p.X278_splice | Splice Site (SNP) | VAF 163/366 reads (45%) | catalogued as COSV51622717; called by muse, mutect2, varscan2
- AP1M1 | c.185A>G p.H62R | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs201225112, COSV99358474; called by muse, mutect2, varscan2
- APC | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 53/212 reads (25%) | catalogued as rs1314843920, CM013690, COSV57335557; called by muse, mutect2, varscan2
- APC | c.4364dup p.N1455Kfs*2 | Frame Shift Ins (INS) | VAF 54/273 reads (20%) | catalogued as COSV57364337; called by mutect2, pindel, varscan2
- API5 | c.281A>T p.N94I | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.852); catalogued as COSV101124557; called by muse, mutect2, varscan2
- ARFGEF3 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs778211953, COSV99294016; called by muse, mutect2, varscan2
- ARHGAP11A | c.69del p.K24Rfs*19 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | catalogued as COSV64381595; called by mutect2, varscan2
- ARHGAP29 | c.1603T>C p.F535L | Missense Mutation (SNP) | VAF 11/343 reads (3%) | SIFT tolerated (0.65); PolyPhen benign (0.062); catalogued as COSV53117372, COSV99558452; called by muse, mutect2
- ARHGEF10 | c.905A>G p.N302S (on ENST00000398564; = p.N277S on NM_014629.4) | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50646353; called by muse, mutect2, varscan2
- ARID4A | c.1266del p.D423Tfs*2 | Frame Shift Del (DEL) | VAF 34/100 reads (34%) | catalogued as rs776520069; called by mutect2, varscan2
- ASPM | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs769866190, COSV99660658; called by muse, mutect2, varscan2
- ASTE1 | c.449A>G p.N150S | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV99393882; called by muse, mutect2
- ATP2B4 | c.2203A>T p.K735* | Nonsense Mutation (SNP) | VAF 9/139 reads (6%) | catalogued as COSV100397704; called by muse, mutect2
- BBS10 | c.198-2A>G p.X66_splice | Splice Site (SNP) | VAF 62/228 reads (27%) | catalogued as COSV99675231; called by muse, mutect2, varscan2
- BCL9 | c.1499T>C p.M500T | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99325389; called by muse, varscan2
- BMP4 | c.1178T>C p.V393A | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55415423; called by muse, mutect2
- BNIP5 | c.1169-2A>G p.X390_splice | Splice Site (SNP) | VAF 57/249 reads (23%) | catalogued as rs758927618, COSV101465171; called by muse, mutect2, varscan2
- C20orf194 | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.308); catalogued as rs151271545, COSV52694667; called by muse, mutect2, varscan2
- C3AR1 | c.1433A>G p.N478S | Missense Mutation (SNP) | VAF 108/411 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV99368712; called by muse, mutect2, varscan2
- C7 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775095625, COSV57472920; called by muse, mutect2, varscan2
- CAAP1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.805); catalogued as COSV100445211, COSV61701108; called by muse, mutect2, varscan2
- CACNA1E | c.6675G>T p.Q2225H (on ENST00000367573 / NM_001205293.3; = p.Q2182H on NM_000721.4) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV62390483; called by muse, mutect2, varscan2
- CALD1 | c.335A>G p.Q112R | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV62645034; called by muse, mutect2, varscan2
- CAMK2B | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99323212; called by muse, varscan2
- CAMTA1 | c.4285G>T p.D1429Y | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100351111; called by muse, mutect2, varscan2
- CAMTA1 | c.4477G>A p.A1493T | Missense Mutation (SNP) | VAF 71/260 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs1353421341, COSV100351115; called by muse, mutect2, varscan2
- CC2D2B | c.162T>A p.F54L | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV60357708; called by muse, mutect2
- CCDC141 | c.3727A>G p.S1243G | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV55372125; called by muse, mutect2, varscan2
- CCDC170 | c.588+2T>C p.X196_splice | Splice Site (SNP) | VAF 46/213 reads (22%) | catalogued as COSV99498571; called by muse, mutect2, varscan2
- CCDC170 | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs770534076, COSV53342478; called by muse, mutect2, varscan2
- CCHCR1 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748422751, COSV52535330; called by muse, mutect2, varscan2
- CCNB3 | c.3716C>T p.S1239F | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99329316; called by muse, mutect2
- CCT6A | c.820del p.I274* | Frame Shift Del (DEL) | VAF 41/220 reads (19%) | catalogued as rs1482449902; called by mutect2, pindel, varscan2
- CD36 | c.1180A>G p.K394E | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.338); catalogued as COSV99987642; called by muse, mutect2, varscan2
- CDK2 | c.116+2T>C p.X39_splice | Splice Site (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99906758; called by muse, mutect2
- CELSR2 | c.7990G>A p.G2664S | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.033); catalogued as rs773564041, COSV99604184; called by muse, mutect2, varscan2
- CEMIP | c.232T>A p.S78T | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV54991175; called by muse, mutect2, varscan2
- CEMIP | c.3770G>A p.R1257H | Missense Mutation (SNP) | VAF 172/674 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs201722725; called by muse, mutect2, varscan2
- CENPE | c.7874A>G p.Q2625R | Missense Mutation (SNP) | VAF 91/327 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.056); catalogued as rs772361306, COSV99478382; called by muse, mutect2, varscan2
- CEP170 | c.3203T>C p.L1068P | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100317337; called by muse, mutect2, varscan2
- CERS2 | c.741+2T>C p.X247_splice | Splice Site (SNP) | VAF 87/411 reads (21%) | catalogued as COSV99645115; called by muse, mutect2, varscan2
- CERS3 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746497056, COSV99432277; called by muse, varscan2
- CFAP46 | c.6925A>G p.R2309G | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV99585116; called by muse, mutect2, varscan2
- CFAP47 | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 84/312 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99935373; called by muse, mutect2, varscan2
- CHD7 | c.3254A>G p.E1085G | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71109295; called by muse, mutect2, varscan2
- CHI3L2 | c.301A>G p.I101V | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs761782008, COSV63874683; called by muse, mutect2, varscan2
- CHRNB3 | c.155A>G p.D52G | Missense Mutation (SNP) | VAF 147/411 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV99251292; called by muse, mutect2, varscan2
- CKAP4 | c.1481G>T p.G494V | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV65172357; called by muse, mutect2
- CLASP2 | c.2302C>T p.R768W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1404612941, COSV56280491; called by muse, mutect2, varscan2
- CLCA4 | c.247A>G p.N83D | Missense Mutation (SNP) | VAF 52/616 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV55367648; called by muse, mutect2
- CLEC14A | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60561827; called by muse, mutect2, varscan2
- CLN8 | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100486082; called by muse, mutect2
- CLRN1 | c.557C>T p.T186I (on ENST00000327047 / NM_174878.3; = p.T110I on NM_052995.2) | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV99902490; called by muse, mutect2
- CNR1 | c.86A>G p.Q29R | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.015); catalogued as COSV100759254; called by muse, mutect2, varscan2
- COG2 | c.380del p.K127Rfs*5 | Frame Shift Del (DEL) | VAF 42/177 reads (24%) | catalogued as rs1188081815, COSV100794718; called by mutect2, varscan2
- COIL | c.587dup p.A197Gfs*2 | Frame Shift Ins (INS) | VAF 54/281 reads (19%) | catalogued as rs748995811; called by mutect2, varscan2
- COL1A2 | c.3562A>G p.M1188V | Missense Mutation (SNP) | VAF 59/250 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as rs751066207, COSV99800264; called by muse, mutect2, varscan2
- COLEC12 | c.85A>G p.K29E | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs1243632874, COSV101232109; called by muse, mutect2, varscan2
- CPNE3 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.685); catalogued as COSV52204523, COSV99547802; called by muse, mutect2
- CPT1C | c.1748G>A p.C583Y | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99773521; called by muse, mutect2, varscan2
- CRNKL1 | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 32/484 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV100131725; called by muse, mutect2
- CTIF | c.689del p.G230Afs*26 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | catalogued as rs1381238054, COSV99838187; called by mutect2, pindel, varscan2
- CTTNBP2 | c.4187A>C p.Q1396P | Missense Mutation (SNP) | VAF 8/240 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99354272; called by muse, mutect2
- CXCR6 | c.113A>C p.Y38S | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99945869; called by muse, mutect2, varscan2
- DAB2IP | c.3073dup p.H1025Pfs*4 (on ENST00000408936; = p.H997Pfs*4 on NM_032552.3) | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | catalogued as rs751187768; called by mutect2, varscan2
- DCX | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 141/580 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs892512121, COSV57566410; called by muse, mutect2, varscan2
- DDX43 | c.1338G>T p.M446I | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as COSV100944007, COSV64813164; called by muse, mutect2, varscan2
- DEFB129 | c.333del p.F111Lfs*15 | Frame Shift Del (DEL) | VAF 72/428 reads (17%) | catalogued as rs765896284; called by mutect2, pindel, varscan2
- DENND3 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs1291941080, COSV52807249; called by muse, mutect2
- DENND5A | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV100064920, COSV104407158; called by muse, mutect2
- DGKE | c.743A>G p.Q248R | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99401021; called by muse, mutect2, varscan2
- DLGAP2 | c.2919C>G p.D973E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.91); catalogued as COSV70097101; called by muse, mutect2, varscan2
- DNAAF5 | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs768679540, COSV52420253, COSV99859994; called by muse, mutect2, varscan2
- DNAH5 | c.4225C>G p.L1409V | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99451278; called by muse, mutect2, varscan2
- DNAH7 | c.3193C>T p.R1065C | Missense Mutation (SNP) | VAF 90/299 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557093519, COSV100415994; called by muse, mutect2, varscan2
- DNAJC28 | c.686A>G p.K229R | Missense Mutation (SNP) | VAF 123/428 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV58721446, COSV58721538; called by muse, mutect2, varscan2
- DOK3 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV100467186; called by muse, mutect2, varscan2
- DPH1 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs371816907, COSV53983881; called by muse, mutect2, varscan2
- DPYS | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100679828; called by muse, mutect2, varscan2
- DSE | c.38T>C p.F13S | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); catalogued as COSV100528660; called by muse, mutect2, varscan2
- DSG1 | c.1631T>C p.V544A | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV99936199; called by mutect2, varscan2
- DUSP16 | c.662C>A p.P221Q | Missense Mutation (SNP) | VAF 138/525 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99963225; called by muse, mutect2, varscan2
- DXO | c.314A>G p.H105R | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV100514744; called by muse, mutect2, varscan2
- DZIP3 | c.825del p.Q276Sfs*2 | Frame Shift Del (DEL) | VAF 34/187 reads (18%) | catalogued as rs901358284; called by mutect2, pindel, varscan2
- ECE1 | c.340T>G p.S114A | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV99942024; called by muse, mutect2, varscan2
- EDIL3 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs1173726255, COSV99677468; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.295dup p.X99_splice | Splice Site (INS) | VAF 16/76 reads (21%) | catalogued as rs756314578; called by mutect2, varscan2
- EHHADH | c.221T>C p.L74P | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99213241; called by muse, mutect2, varscan2
- EHMT2 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.416); catalogued as rs1349695575, COSV100977226; called by muse, mutect2, varscan2
- ELAVL4 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1341487754, COSV63915503; called by muse, mutect2, varscan2
- EMC1 | c.2713C>T p.H905Y | Missense Mutation (SNP) | VAF 81/294 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.486); catalogued as COSV100916456; called by muse, mutect2, varscan2
- ENPP3 | c.1213del p.R405Afs*36 | Frame Shift Del (DEL) | VAF 80/366 reads (22%) | catalogued as COSV62954163; called by mutect2, pindel, varscan2
- ERBB3 | c.2300A>G p.D767G | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99917280; called by muse, mutect2, varscan2
- ESX1 | c.810G>A p.M270I | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV65424194; called by muse, mutect2, varscan2
- ETAA1 | c.369del p.K123Nfs*46 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | catalogued as rs1298232483; called by pindel, varscan2
- EXOC6B | c.1784G>A p.G595D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55552056; called by muse, mutect2, varscan2
- EXOSC7 | c.876A>G p.*292Wext*? | Nonstop Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99652067; called by muse, mutect2, varscan2
- EZHIP | c.1295_1297dup p.S432dup | In Frame Ins (INS) | VAF 30/118 reads (25%) | catalogued as rs781810516; called by mutect2, varscan2
- FAM120C | c.2739T>G p.F913L | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.88); PolyPhen benign (0.014); catalogued as COSV100070231; called by muse, mutect2
- FAM13C | c.1695A>G p.I565M | Missense Mutation (SNP) | VAF 75/291 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99514140; called by muse, mutect2, varscan2
- FAM155A | c.143T>C p.F48S | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV65588700; called by muse, mutect2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | catalogued as rs748967872; called by mutect2, varscan2
- FBXO30 | c.2034G>A p.K678= | Splice Region (SNP) | VAF 74/313 reads (24%) | catalogued as rs1411784444, COSV99395259; called by muse, mutect2, varscan2
- FBXW7 | c.1419-2A>C p.X473_splice (on ENST00000281708 / NM_001349798.2; = p.X393_splice on NM_018315.5) | Splice Site (SNP) | VAF 32/167 reads (19%) | catalogued as COSV55891424, COSV55939484; called by muse, mutect2, varscan2
- FGF23 | c.392A>C p.Q131P | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV52976443, COSV99426756; called by muse, mutect2, varscan2
- FLT1 | c.2703A>T p.Q901H | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV99163349; called by muse, mutect2
- FMO4 | c.825A>G p.K275= | Splice Region (SNP) | VAF 35/152 reads (23%) | catalogued as COSV100882085; called by muse, mutect2, varscan2
- FNDC7 | c.1522A>G p.T508A | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV99601391; called by muse, mutect2, varscan2
- FOLR3 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as rs1287584454, COSV61529960; called by muse, mutect2, varscan2
- FXR1 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.993); catalogued as rs762872016, COSV99976481; called by muse, mutect2
- FYB1 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 100/413 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757881072, COSV60943139; called by muse, mutect2, varscan2
- GABRA4 | c.579T>C p.Y193= | Splice Region (SNP) | VAF 40/153 reads (26%) | catalogued as COSV99974247; called by muse, mutect2, varscan2
- GABRR2 | c.590A>C p.E197A | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV68764707; called by muse, mutect2, varscan2
- GAST | c.209C>A p.A70E | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV100268048; called by muse, mutect2, varscan2
- GCC1 | c.1732A>G p.T578A | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100365570; called by muse, mutect2, varscan2
- GCM2 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as rs368814748; called by muse, mutect2, varscan2
- GCN1 | c.5093C>T p.P1698L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs749928955, COSV100325553, COSV56106630; called by muse, mutect2, varscan2
- GHDC | c.505A>G p.N169D | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV56987644; called by muse, mutect2, varscan2
- GLP1R | c.1044-2A>G p.X348_splice | Splice Site (SNP) | VAF 17/81 reads (21%) | catalogued as COSV100952651; called by muse, mutect2, varscan2
- GLUD2 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60153043; called by muse, mutect2, varscan2
- GMIP | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as COSV52284827; called by muse, mutect2, varscan2
- GOLGA3 | c.3968A>T p.Q1323L | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99210673; called by muse, mutect2, varscan2
- GOLGA3 | c.2507A>G p.K836R | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.165); catalogued as COSV99210718; called by muse, mutect2
- GPR183 | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs780174780, COSV63117726; called by muse, mutect2, varscan2
- GPX5 | c.290T>C p.L97S | Missense Mutation (SNP) | VAF 140/978 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1346288692, COSV101297275; called by muse, mutect2, varscan2
- GRHL2 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145433541, COSV52548771, COSV52554397; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 56/244 reads (23%) | catalogued as rs760757380; called by mutect2, varscan2
- GRM4 | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 63/303 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1338131065, COSV65212346; called by muse, mutect2, varscan2
- GRM8 | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV58819290; called by muse, mutect2, varscan2
- GSTCD | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 59/291 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.279); catalogued as rs199886614, COSV100853857; called by muse, mutect2, varscan2
- GUCY1A1 | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.044); catalogued as COSV99638053; called by muse, mutect2, varscan2
- HACD2 | c.743A>G p.E248G | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV101046022; called by muse, mutect2
- HARS1 | c.1417G>C p.D473H | Missense Mutation (SNP) | VAF 21/252 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100298126, COSV56908692; called by muse, mutect2
- HCFC2 | c.866T>C p.L289P | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99983167; called by muse, mutect2, varscan2
- HDAC8 | c.551-2A>G p.X184_splice | Splice Site (SNP) | VAF 37/182 reads (20%) | catalogued as COSV101003329; called by muse, mutect2, varscan2
- HIP1 | c.1106A>G p.N369S | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV100417746; called by muse, mutect2, varscan2
- HIVEP3 | c.3002A>G p.H1001R | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV99913125; called by muse, mutect2, varscan2
- HMCN1 | c.3533A>G p.K1178R | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54908430, COSV99631359; called by muse, mutect2, varscan2
- HPD | c.18C>A p.D6E | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.414); catalogued as COSV100000157; called by muse, mutect2, varscan2
- HSD17B11 | c.812+2T>C p.X271_splice | Splice Site (SNP) | VAF 32/217 reads (15%) | catalogued as rs770673158, COSV100839603; called by muse, mutect2, varscan2
- HTR1A | c.1024A>G p.K342E | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100109158; called by muse, varscan2
- HTT | c.3386T>C p.L1129P | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61860705; called by muse, mutect2, varscan2
- HUWE1 | c.6475G>A p.A2159T | Missense Mutation (SNP) | VAF 89/372 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99473039; called by muse, mutect2, varscan2
- IDO2 | c.2T>C p.M1? (on ENST00000389060; = p.M14T on NM_194294.2) | Translation Start Site (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV58424932; called by muse, mutect2
- IFT140 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.789); catalogued as rs774892063, COSV68485762; called by muse, mutect2
- IGSF5 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.251); catalogued as rs371000620; called by muse, mutect2, varscan2
- IKZF4 | c.563A>G p.H188R | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as COSV100009187; called by muse, mutect2, varscan2
- IL32 | c.674A>G p.Q225R (on ENST00000396890 / NM_001308078.4; = p.Q179R on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV99145519; called by muse, mutect2, varscan2
- IMPG1 | c.1213-2A>G p.X405_splice | Splice Site (SNP) | VAF 24/87 reads (28%) | catalogued as rs1192515384, COSV100886483; called by muse, mutect2, varscan2
- IQCH | c.2663C>T p.A888V | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs142903968; called by muse, mutect2, varscan2
- IQGAP3 | c.4364C>T p.A1455V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as COSV100752199; called by muse, mutect2
- IRS4 | c.2398T>C p.S800P | Missense Mutation (SNP) | VAF 67/301 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100929611; called by muse, mutect2, varscan2
- ITPR2 | c.5948C>T p.A1983V | Missense Mutation (SNP) | VAF 62/239 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.679); catalogued as rs1271921653, COSV101190051; called by muse, mutect2, varscan2
- JARID2 | c.493+2T>C p.X165_splice | Splice Site (SNP) | VAF 41/231 reads (18%) | catalogued as COSV100522006, COSV59195306; called by muse, mutect2, varscan2
- KAT7 | c.542T>G p.F181C | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV99371856; called by muse, mutect2
- KCNA3 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); catalogued as COSV63902245; called by muse, mutect2, varscan2
- KCNB2 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 105/558 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.932); catalogued as COSV101578862; called by muse, mutect2, varscan2
- KCNH4 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs1215616306, COSV52916758; called by muse, mutect2, varscan2
- KCNQ5 | c.1247G>T p.S416I | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV59688953; called by muse, mutect2, varscan2
- KCNV2 | c.949T>C p.Y317H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101172619; called by muse, mutect2, varscan2
- KCTD14 | c.73dup p.R25Pfs*18 | Frame Shift Ins (INS) | VAF 9/22 reads (41%) | catalogued as rs763060357; called by mutect2, varscan2
- KCTD2 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.95); PolyPhen benign (0.028); catalogued as rs202181641, COSV100483315; called by muse, mutect2, varscan2
- KHDRBS2 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 48/208 reads (23%) | catalogued as COSV99834981; called by muse, varscan2
- KHDRBS2 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99834982; called by muse, varscan2
- KIF19 | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63429272; called by muse, mutect2, varscan2
- KIF4A | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 20/516 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV65542704; called by muse, mutect2
- KIF5C | c.1421A>G p.Q474R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as rs1437370237, COSV68479900, COSV68480762; called by muse, mutect2, varscan2
- KIT | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.039); catalogued as COSV55397507; called by muse, mutect2, varscan2
- KL | c.2557C>T p.R853C | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147992424; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL1 | c.1264A>G p.N422D | Missense Mutation (SNP) | VAF 17/319 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64770695; called by muse, mutect2
- KLHL5 | c.2214T>C p.V738= | Splice Region (SNP) | VAF 30/123 reads (24%) | catalogued as COSV99785513; called by muse, mutect2, varscan2
- KNL1 | c.886A>G p.I296V (on ENST00000346991 / NM_170589.5; = p.I270V on NM_144508.5) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61153685; called by muse, mutect2, varscan2
- LAMA2 | c.6455G>T p.G2152V | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV101370602; called by muse, mutect2, varscan2
- LAMB3 | c.3511T>C p.C1171R | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99151712; called by muse, mutect2, varscan2
- LARP1 | c.1964G>A p.R655Q (on ENST00000518297 / NM_033551.3; = p.R578Q on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs918565873, COSV100303882; called by muse, mutect2, varscan2
- LARP4 | c.2149T>C p.Y717H | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.027); catalogued as COSV99529355; called by muse, mutect2
- LEPR | c.3302C>T p.S1101L | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267598694, COSV62747060; called by muse, mutect2, varscan2
- LIAS | c.584A>C p.E195A (on ENST00000261434 / NM_001363700.2; = p.E298A on NM_006859.4) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV99787747; called by muse, varscan2
- LRG1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs754452460, COSV56703351; called by muse, mutect2, varscan2
- LRP4 | c.3752C>A p.P1251Q | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.451); catalogued as COSV101066705; called by muse, mutect2, varscan2
- LRPPRC | c.3828A>T p.R1276S | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV99580941; called by muse, mutect2, varscan2
- LRRC37A2 | c.3697A>G p.T1233A | Missense Mutation (SNP) | VAF 17/418 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100238781; called by muse, mutect2
- LY75-CD302 | c.5343dup p.G1782Rfs*4 | Frame Shift Ins (INS) | VAF 29/165 reads (18%) | catalogued as rs1190921676; called by mutect2, varscan2
- MACF1 | c.2063G>A p.R688K | Missense Mutation (SNP) | VAF 16/373 reads (4%) | catalogued as COSV100485216; called by muse, mutect2
- MAGT1 | c.407C>T p.A136V (on ENST00000618282 / NM_001367916.1; = p.A168V on NM_032121.5) | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.751); catalogued as COSV100800328; called by muse, mutect2, varscan2
- MAMDC2 | c.1439A>G p.D480G | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV65852342; called by muse, mutect2, varscan2
- MAP3K2 | c.530T>G p.V177G | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.638); catalogued as COSV61293906; called by muse, mutect2, varscan2
- MAST1 | c.3095T>C p.V1032A | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52257878; called by muse, mutect2, varscan2
- MAU2 | c.1562T>C p.M521T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99448840; called by muse, mutect2, varscan2
- MBTPS1 | c.2944G>A p.A982T | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.972); catalogued as rs145043514; called by muse, mutect2, varscan2
- MCPH1 | c.1402dup p.T468Nfs*5 | Frame Shift Ins (INS) | VAF 34/240 reads (14%) | catalogued as rs768835889; called by mutect2, varscan2
- MDC1 | c.5453T>C p.M1818T | Missense Mutation (SNP) | VAF 75/318 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV64524197; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MED13 | c.5692A>T p.M1898L | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV101181163; called by muse, mutect2, varscan2
- MGAT4C | c.1174del p.I392Lfs*3 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | catalogued as rs746398787; called by mutect2, varscan2
- MLH3 | c.1198T>G p.S400A | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as COSV99465113; called by muse, mutect2, varscan2
- MME | c.1186A>G p.K396E | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV100852439; called by muse, mutect2, varscan2
- MMP26 | c.377A>C p.N126T | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.085); catalogued as COSV100332149; called by muse, mutect2, varscan2
- MPP6 | c.917dup p.K307Efs*14 | Frame Shift Ins (INS) | VAF 42/276 reads (15%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MSH4 | c.2091G>T p.Q697H | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV54201366; called by muse, mutect2
- MTCL1 | c.5269A>G p.T1757A (on ENST00000306329 / NM_001378206.1; = p.T1438A on NM_015210.4) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as rs747047832, COSV100094949; called by muse, mutect2
- MTFR1 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs762061807, COSV50951535; called by muse, mutect2, varscan2
- MTMR7 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376725869; called by muse, mutect2, varscan2
- MUC17 | c.12615C>A p.N4205K | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs746069097, COSV100074015; called by muse, mutect2, varscan2
- MUC4 | c.1955C>T p.T652M | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.788); catalogued as rs368190725; called by muse, mutect2, varscan2
- MUS81 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 57/234 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100337285; called by muse, mutect2, varscan2
- MYH11 | c.4798G>A p.E1600K | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761463510, COSV55550205; called by muse, mutect2
- MYH3 | c.5332G>A p.A1778T | Missense Mutation (SNP) | VAF 68/203 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs1272471978, COSV56867624; called by muse, mutect2, varscan2
- MYLK3 | c.1277C>G p.T426R | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV101189139, COSV67363934; called by muse, mutect2, varscan2
- MYOCD | c.1660A>G p.R554G | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV100590979; called by muse, mutect2, varscan2
- MYOF | c.4901T>C p.V1634A | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs762684800, COSV63702975; called by muse, mutect2, varscan2
- NAALADL1 | c.458A>G p.Y153C | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758878384, COSV100368140; called by muse, mutect2
- NAF1 | c.650T>C p.M217T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as COSV99919213; called by muse, mutect2
- NAPEPLD | c.842T>C p.F281S | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1008762007, COSV100439928; called by muse, mutect2, varscan2
- NCAPD2 | c.3484G>A p.A1162T | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as rs746072942, COSV57520863; called by muse, mutect2, varscan2
- NCDN | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs1326831347, COSV57844623, COSV57851383; called by muse, mutect2, varscan2
- NCKAP5 | c.4235G>A p.R1412H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs368087471, COSV58439016; called by muse, mutect2, varscan2
- NCOA1 | c.2101G>T p.D701Y | Missense Mutation (SNP) | VAF 55/276 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99946468; called by muse, mutect2, varscan2
- NDST4 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 74/290 reads (26%) | catalogued as COSV99996969; called by muse, mutect2, varscan2
- NEB | c.4804T>C p.Y1602H | Missense Mutation (SNP) | VAF 7/196 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as COSV51459385, COSV99424845; called by muse, mutect2
- NECTIN1 | c.1244A>T p.N415I | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV99872369; called by muse, mutect2, varscan2
- NFKB1 | c.722A>G p.D241G (on ENST00000394820 / NM_001382627.1; = p.D242G on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99897445; called by muse, mutect2, varscan2
- NKTR | c.1304del p.K435Rfs*31 | Frame Shift Del (DEL) | VAF 61/264 reads (23%) | catalogued as rs867098093; called by mutect2, varscan2
- NLGN3 | c.332A>G p.H111R | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100704852; called by muse, mutect2
- NLRP8 | c.3122A>G p.D1041G | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV52586062; called by muse, mutect2
- NMNAT3 | c.197C>T p.A66V (on ENST00000296202 / NM_001320512.1; = p.A29V on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as rs143845479; called by muse, mutect2, varscan2
- NOC2L | c.1834G>A p.G612R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV100498086; called by muse, mutect2
- NR4A2 | c.998T>C p.V333A | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100277245; called by muse, mutect2, varscan2
- NRAP | c.1247T>C p.M416T (on ENST00000359988 / NM_001322945.2; = p.M381T on NM_006175.4) | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV100748492; called by muse, mutect2, varscan2
- NUP210 | c.1013G>A p.S338N | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.631); catalogued as rs1359017333, COSV99596459; called by muse, mutect2, varscan2
- NWD1 | c.4021T>C p.Y1341H | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV60341015; called by muse, mutect2
- OBSCN | c.2838G>T p.R946S | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV99480956; called by muse, mutect2, varscan2
- OLFM2 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs747490195, COSV53433728; called by muse, mutect2, varscan2
- OMD | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 96/359 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs972078422, COSV100979065; called by muse, mutect2, varscan2
- OPN1MW | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100884393; called by muse, mutect2, varscan2
- OPRPN | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 87/898 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as rs373411935; called by muse, mutect2
- OR2F1 | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 206/755 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV101231292, COSV101231316; called by muse, mutect2, varscan2
- OR2M7 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 131/573 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs144015069, COSV58738011; called by muse, mutect2, varscan2
- OR5I1 | c.539dup p.C181Lfs*2 | Frame Shift Ins (INS) | VAF 38/156 reads (24%) | catalogued as rs757816304; called by mutect2, pindel, varscan2
- OR6K2 | c.137T>C p.I46T | Missense Mutation (SNP) | VAF 118/466 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs143338906, COSV62744341; called by muse, mutect2, varscan2
- OXR1 | c.2395A>G p.T799A (on ENST00000442977 / NM_001198532.1; = p.T771A on NM_018002.3) | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV52425026; called by muse, mutect2, varscan2
- PACSIN1 | c.1104del p.F369Lfs*118 | Frame Shift Del (DEL) | VAF 33/151 reads (22%) | catalogued as COSV55061755; called by mutect2, pindel, varscan2
- PARP14 | c.4409A>G p.K1470R | Missense Mutation (SNP) | VAF 154/499 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV71734452; called by muse, mutect2, varscan2
- PAXIP1 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1185835451, COSV101249845; called by muse, mutect2, varscan2
- PCDHB14 | c.1045A>G p.I349V | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV99506064; called by muse, mutect2, varscan2
- PCDHB5 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 87/350 reads (25%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.014); catalogued as COSV50649167; called by muse, mutect2, varscan2
- PCDHGA2 | c.535T>A p.S179T | Missense Mutation (SNP) | VAF 72/248 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); catalogued as COSV53930939; called by muse, mutect2, varscan2
- PCDHGA8 | c.2362_2363insT p.N788Ifs*2 | Frame Shift Ins (INS) | VAF 24/88 reads (27%) | catalogued as COSV53930944; called by mutect2, pindel, varscan2
- PCDHGC5 | c.1667A>G p.D556G | Missense Mutation (SNP) | VAF 50/344 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99340901; called by muse, mutect2, varscan2
- PCNX2 | c.5248C>T p.R1750W | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528200127, COSV50787897; called by muse, mutect2, varscan2
- PCSK6 | c.2186G>A p.C729Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV61852049; called by muse, mutect2, varscan2
- PDP2 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs139343061; called by muse, mutect2, varscan2
- PDZD2 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1387630551, COSV99224305, COSV99225600; called by muse, mutect2, varscan2
- PIK3CB | c.2941C>A p.R981= | Splice Region (SNP) | VAF 34/205 reads (17%) | catalogued as rs966729151, COSV100005805; called by muse, mutect2, varscan2
- PIKFYVE | c.160C>A p.R54S | Missense Mutation (SNP) | VAF 92/355 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100011010, COSV52237901; called by muse, mutect2, varscan2
- PILRA | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 80/274 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs764890538, COSV99546567; called by muse, mutect2, varscan2
- PIR | c.395A>G p.Q132R | Missense Mutation (SNP) | VAF 97/367 reads (26%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.972); catalogued as COSV100990681; called by muse, mutect2, varscan2
- PKHD1L1 | c.96A>C p.K32N | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); catalogued as COSV65741408; called by muse, mutect2, varscan2
- PLCB1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs761393253, COSV100571455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLGRKT | c.227del p.K76Rfs*12 | Frame Shift Del (DEL) | VAF 44/200 reads (22%) | catalogued as rs765091847; called by mutect2, varscan2
- PLXDC1 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs143773186; called by muse, mutect2, varscan2
- PML | c.2452G>A p.G818R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs754603424, COSV99167449; called by muse, mutect2, varscan2
- POM121L12 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.235); catalogued as COSV101374940; called by muse, mutect2, varscan2
- POTEF | c.2237del p.G746Afs*20 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | catalogued as rs760191584; called by pindel, varscan2
- PPARD | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1453840099, COSV61099453; called by muse, mutect2, varscan2
- PPP2R2A | c.1321A>G p.I441V | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV100277256; called by muse, mutect2, varscan2
- PRAMEF4 | c.354G>A p.W118* | Nonsense Mutation (SNP) | VAF 32/655 reads (5%) | catalogued as rs1204271130, COSV52438200; called by muse, mutect2
- PRDM1 | c.1251dup p.Y418Lfs*6 | Frame Shift Ins (INS) | VAF 24/107 reads (22%) | catalogued as rs961279924; called by mutect2, pindel, varscan2
- PRKCD | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV100387939; called by muse, mutect2, varscan2
- PRMT8 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54211707; called by muse, mutect2, varscan2
- PSMA5 | c.455A>C p.Q152P | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99600594; called by muse, mutect2, varscan2
- PTPRT | c.503T>A p.V168D | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100628484; called by muse, mutect2
- PXDC1 | c.460A>C p.I154L | Missense Mutation (SNP) | VAF 82/310 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV66661537; called by muse, mutect2, varscan2
- PXYLP1 | c.1022A>G p.Y341C | Missense Mutation (SNP) | VAF 126/411 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99649565; called by muse, mutect2, varscan2
- PYHIN1 | c.1000A>C p.T334P | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV100932370; called by muse, mutect2, varscan2
- R3HDM2 | c.2737del p.D913Tfs*41 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as COSV100234622; called by mutect2, pindel, varscan2
- RAD51AP2 | c.2377G>A p.A793T | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.255); catalogued as COSV67587806; called by muse, varscan2
- RAE1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 101/540 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as rs779378832, COSV64797881; called by muse, mutect2, varscan2
- RASL11A | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV99611103; called by muse, mutect2, varscan2
- RBAK | c.568A>G p.N190D | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100806701; called by muse, mutect2
- RELN | c.7969A>G p.N2657D | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100634102; called by muse, mutect2, varscan2
- REXO4 | c.107G>T p.R36M | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV100747131; called by muse, mutect2, varscan2
- RIC8B | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100822653, COSV62693388; called by muse, mutect2, varscan2
- RIN1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs141887009; called by muse, mutect2, varscan2
- RIOK1 | c.82_83del p.D28Lfs*9 | Frame Shift Del (DEL) | VAF 46/212 reads (22%) | catalogued as rs1412429262; called by pindel, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 64/278 reads (23%) | catalogued as rs757038390; called by mutect2, varscan2
- RO60 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.156); catalogued as rs201998409, COSV66473229; called by muse, mutect2, varscan2
- RPS6KA1 | c.1104dup p.S369Qfs*47 | Frame Shift Ins (INS) | VAF 12/56 reads (21%) | catalogued as rs745561139; called by mutect2, varscan2
- RRBP1 | c.2179A>G p.N727D (on ENST00000377813 / NM_001365613.2; = p.N294D on NM_004587.3) | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV55701422, COSV99854236; called by muse, mutect2
- RSF1 | c.3944A>G p.H1315R | Missense Mutation (SNP) | VAF 78/329 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100407394; called by muse, mutect2, varscan2
- RXRG | c.52T>C p.S18P | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100717658; called by muse, mutect2, varscan2
- RYR1 | c.5797G>T p.E1933* | Nonsense Mutation (SNP) | VAF 49/197 reads (25%) | catalogued as rs183999225, COSV100616182; called by muse, mutect2, varscan2
- S1PR3 | c.1025G>A p.S342N | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.449); catalogued as COSV100822559; called by muse, mutect2, varscan2
- SDHA | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.072); catalogued as rs878854635, COSV53767265; ClinVar: uncertain significance; called by muse, mutect2
- SEC31B | c.2749A>G p.M917V | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100947358; called by muse, mutect2, varscan2
- SEL1L2 | c.767G>C p.S256T | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV53151128; called by muse, mutect2, varscan2
- SFRP5 | c.917A>G p.Y306C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as COSV99823205; called by muse, mutect2, varscan2
- SH3PXD2A | c.2225C>T p.A742V (on ENST00000369774 / NM_001365079.1; = p.A714V on NM_014631.2) | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs765874609, COSV60116806; called by muse, mutect2, varscan2
- SHANK1 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99521508; called by muse, mutect2, varscan2
- SHROOM3 | c.5537A>G p.N1846S | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.179); catalogued as COSV99934700; called by muse, mutect2
- SI | c.3386A>T p.N1129I | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV100016166, COSV52296733; called by muse, mutect2, varscan2
- SIDT1 | c.659T>C p.I220T | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99334251; called by muse, mutect2
- SIGLEC1 | c.3827C>A p.P1276H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99167686; called by muse, mutect2, varscan2
- SLC10A3 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV54836099; called by muse, mutect2, varscan2
- SLC13A1 | c.1013A>G p.Q338R | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV52013000; called by muse, mutect2, varscan2
- SLC14A2 | c.1477T>A p.F493I | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV99675722; called by muse, mutect2, varscan2
- SLC16A12 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs755537113, COSV100370322; called by muse, mutect2
- SLC20A2 | c.353T>A p.I118N | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100646125; called by muse, mutect2, varscan2
- SLC38A7 | c.796A>G p.N266D | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.671); catalogued as COSV54702866; called by muse, mutect2, varscan2
- SLC4A11 | c.1877A>C p.H626P | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs779779012, COSV101196052; called by muse, mutect2, varscan2
- SLC4A1AP | c.316A>G p.T106A | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV58134480; called by muse, mutect2
- SLC4A3 | c.3095G>T p.G1032V | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99812972; called by muse, mutect2
- SLCO3A1 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100574843, COSV100575616; called by muse, mutect2, varscan2
- SMARCC2 | c.1866A>C p.K622N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57217090; called by muse, mutect2, varscan2
- SMC1B | c.2419A>G p.R807G | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV62528384; called by muse, mutect2, varscan2
- SMC5 | c.2841dup p.S948* | Frame Shift Ins (INS) | VAF 24/86 reads (28%) | catalogued as rs940304838; called by mutect2, varscan2
- SMC6 | c.680T>A p.M227K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.03); catalogued as COSV61173516; called by muse, mutect2, varscan2
- SNAI1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV99723959; called by muse, mutect2, varscan2
- SNRNP200 | c.2585A>G p.D862G | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100107748; called by muse, mutect2, varscan2
- SNX16 | c.866A>C p.E289A | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.101); catalogued as COSV100629659; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 51/195 reads (26%) | catalogued as rs768873484; called by mutect2, varscan2
- SOX5 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58628809, COSV58652994; called by muse, mutect2, varscan2
- SPATA20 | c.652C>T p.R218C (on ENST00000356488 / NM_001258372.1; = p.R234C on NM_022827.4) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs201320543, COSV99135968; called by muse, mutect2
- SPATA33 | c.74A>G p.K25R | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV99498449; called by muse, mutect2
- STEAP4 | c.674A>G p.Y225C | Missense Mutation (SNP) | VAF 73/259 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57327955, COSV57328977; called by muse, mutect2, varscan2
- STRBP | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs758454640, COSV62118011; called by muse, mutect2, varscan2
- STXBP6 | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 56/223 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV100121944; called by muse, mutect2, varscan2
- SUN2 | c.1469G>A p.S490N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV53303130; called by muse, mutect2, varscan2
- SUOX | c.1585C>T p.R529* | Nonsense Mutation (SNP) | VAF 63/295 reads (21%) | catalogued as rs766949012, COSV56267892; called by muse, mutect2, varscan2
- SUPT5H | c.1298T>C p.L433P | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100782088, COSV100782102; called by muse, mutect2, varscan2
- SUV39H1 | c.1014C>A p.D338E | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.181); catalogued as COSV100551807; called by mutect2, varscan2
- SYNM | c.868T>G p.W290G | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as COSV100152824; called by muse, mutect2, varscan2
- TACC2 | c.2078T>C p.L693S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV100552797; called by muse, mutect2, varscan2
- TADA3 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99809555; called by muse, mutect2, varscan2
- TAS1R2 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs777052368, COSV64744334; called by muse, mutect2, varscan2
- TBC1D8B | c.3005T>C p.L1002S | Missense Mutation (SNP) | VAF 101/384 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs752623394, COSV99344620; called by muse, mutect2, varscan2
- TBX19 | c.533A>G p.H178R | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); catalogued as COSV63198485; called by muse, mutect2, varscan2
- TCEANC | c.26C>T p.A9V (on ENST00000380600 / NM_001297563.2; = p.A39V on NM_152634.4) | Missense Mutation (SNP) | VAF 81/299 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.186); catalogued as COSV59039685; called by muse, mutect2, varscan2
- TCF12 | c.546dup p.V183Sfs*21 | Frame Shift Ins (INS) | VAF 50/169 reads (30%) | catalogued as rs1352708150; called by mutect2, varscan2
- TENM1 | c.8020A>G p.R2674G | Missense Mutation (SNP) | VAF 127/565 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.889); catalogued as COSV100950356; called by muse, mutect2, varscan2
- TEP1 | c.2588T>C p.F863S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs755874453, COSV99402712; called by muse, mutect2, varscan2
- TEPP | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs767536762, COSV52043057; called by muse, mutect2, varscan2
- TFB1M | c.727A>G p.K243E | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV99265677; called by muse, mutect2, varscan2
- TGDS | c.673T>C p.S225P | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV54300498; called by muse, mutect2, varscan2
- TINAGL1 | c.761T>C p.L254P | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99592957; called by muse, mutect2, varscan2
- TIRAP | c.536T>A p.L179Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101201644; called by muse, mutect2, varscan2
- TLE3 | c.190T>C p.Y64H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100450579; called by muse, mutect2
- TLR7 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 164/648 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs748708984, COSV66124310; called by muse, mutect2, varscan2
- TMC5 | c.863dup p.E289Rfs*3 | Frame Shift Ins (INS) | VAF 43/152 reads (28%) | catalogued as rs770349191; called by mutect2, pindel, varscan2
- TMCC3 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.741); catalogued as COSV99705551; called by muse, mutect2, varscan2
- TMEM106B | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.761); catalogued as rs746430474, COSV67544781; called by muse, mutect2, varscan2
- TMEM132D | c.2128A>G p.S710G | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101242944; called by muse, mutect2, varscan2
- TMPRSS12 | c.537dup p.A180Sfs*5 | Frame Shift Ins (INS) | VAF 10/57 reads (18%) | catalogued as rs755081902; called by mutect2, varscan2
- TNKS | c.3878T>A p.V1293D | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100127349, COSV60051689; called by muse, mutect2, varscan2
- TOP2A | c.1469T>C p.I490T | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV70732412; called by muse, mutect2, varscan2
- TRAF3IP2 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.112); catalogued as rs141777182; called by muse, mutect2, varscan2
- TRIM13 | c.737T>C p.I246T | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs200905613, COSV100078445; called by muse, mutect2
- TRIM21 | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99587782; called by muse, mutect2, varscan2
- TRMT9B | c.362T>C p.I121T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.377); catalogued as rs1166540470, COSV101501618; called by muse, mutect2
- TRO | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs935196884, COSV51500417; called by muse, mutect2, varscan2
- TRPC4 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 59/333 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100157171; called by muse, mutect2, varscan2
- TRPV3 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs151284467, COSV56788480; ClinVar: benign; called by muse, mutect2, varscan2
- TTC12 | c.1514A>G p.N505S | Missense Mutation (SNP) | VAF 49/273 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100133182; called by muse, mutect2, varscan2
- TTL | c.756C>A p.N252K | Missense Mutation (SNP) | VAF 20/321 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.223); catalogued as COSV51974167; called by muse, mutect2
- TTN | c.76012C>T p.P25338S (on ENST00000591111; = p.P17914S on NM_003319.4) | Missense Mutation (SNP) | VAF 34/178 reads (19%) | PolyPhen probably damaging (0.998); catalogued as COSV59976817; called by muse, mutect2, varscan2
- TUB | c.781dup p.Q261Pfs*31 (on ENST00000299506 / NM_177972.3; = p.Q316Pfs*31 on NM_003320.4) | Frame Shift Ins (INS) | VAF 35/139 reads (25%) | catalogued as rs759016192; called by mutect2, pindel, varscan2
- TXNIP | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 28/632 reads (4%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as COSV100997305; called by muse, mutect2
- UBA2 | c.1253dup p.L418Ffs*3 | Frame Shift Ins (INS) | VAF 32/132 reads (24%) | catalogued as rs766436639; called by mutect2, varscan2
- UBA6 | c.79A>G p.K27E | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as COSV100451761; called by muse, mutect2
- UBE3C | c.313del p.Y105Tfs*10 | Frame Shift Del (DEL) | VAF 51/253 reads (20%) | catalogued as rs1158409559; called by mutect2, pindel, varscan2
- UMODL1 | c.3218T>C p.L1073P (on ENST00000408910 / NM_001004416.2; = p.L1201P on NM_173568.3) | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV68569651; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 69/166 reads (42%) | catalogued as rs767420916; called by mutect2, varscan2
- UQCC3 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.236); catalogued as COSV99583315; called by muse, mutect2, varscan2
- USP20 | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59613036; called by muse, mutect2, varscan2
- USP20 | c.881A>T p.E294V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100204455; called by muse, mutect2
- USP9X | c.5125A>G p.M1709V | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100199610; called by muse, mutect2, varscan2
- UXS1 | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV51676737; called by muse, mutect2, varscan2
- VAMP7 | c.15dup p.A6Cfs*30 | Frame Shift Ins (INS) | VAF 72/399 reads (18%) | catalogued as rs781134359; called by mutect2, pindel, varscan2
- VDR | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV57467107, COSV57467803; called by muse, mutect2, varscan2
- VGLL3 | c.448T>G p.F150V | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV101051976; called by muse, mutect2, varscan2
- VSNL1 | c.62A>C p.E21A | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0.059); catalogued as COSV99723172; called by muse, mutect2, varscan2
- WDFY1 | c.857C>A p.S286Y | Missense Mutation (SNP) | VAF 103/424 reads (24%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.967); catalogued as COSV51789139; called by muse, mutect2, varscan2
- WDR13 | c.896del p.G299Afs*5 | Frame Shift Del (DEL) | VAF 15/74 reads (20%) | catalogued as COSV54333281; called by mutect2, pindel, varscan2
- WDR37 | c.623A>C p.H208P | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99579901; called by muse, mutect2, varscan2
- WDR7 | c.3379A>G p.I1127V | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.456); catalogued as rs375430949; called by muse, mutect2, varscan2
- WTIP | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.258); catalogued as rs747062139, COSV54327263; called by muse, mutect2, varscan2
- XPNPEP1 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59171656; called by muse, mutect2, varscan2
- XRCC5 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101079681; called by muse, mutect2, varscan2
- XYLB | c.778T>C p.S260P | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV99264295; called by muse, mutect2
- YIPF7 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as COSV60656658; called by muse, mutect2
- YTHDF3 | c.1273T>G p.S425A | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV101572400; called by muse, mutect2, varscan2
- YY1AP1 | c.459A>T p.E153D (on ENST00000295566 / NM_139118.2; = p.E76D on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/373 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV99804308; called by muse, mutect2, varscan2
- ZBTB16 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV60091866; called by muse, mutect2, varscan2
- ZC3H11A | c.1930A>G p.R644G | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV59745861, COSV59750825; called by muse, mutect2, varscan2
- ZC3H4 | c.968-2A>C p.X323_splice | Splice Site (SNP) | VAF 55/275 reads (20%) | catalogued as COSV53412087; called by muse, mutect2, varscan2
- ZC3H6 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV59667197; called by muse, mutect2, varscan2
- ZMYM2 | c.853T>A p.W285R | Missense Mutation (SNP) | VAF 62/767 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV67033546; called by muse, mutect2
- ZNF148 | c.1583A>G p.K528R | Missense Mutation (SNP) | VAF 98/320 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100642133; called by muse, mutect2, varscan2
- ZNF197 | c.2185A>G p.T729A | Missense Mutation (SNP) | VAF 82/253 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as COSV100482138; called by muse, mutect2, varscan2
- ZNF226 | c.581dup p.N194Kfs*2 | Frame Shift Ins (INS) | VAF 30/142 reads (21%) | catalogued as rs773388956; called by mutect2, pindel, varscan2
- ZNF257 | c.615A>C p.E205D | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV71306818; called by muse, mutect2, varscan2
- ZNF284 | c.1618C>T p.Q540* | Nonsense Mutation (SNP) | VAF 40/188 reads (21%) | catalogued as COSV101398919, COSV69690883; called by muse, mutect2, varscan2
- ZNF420 | c.1156A>G p.T386A | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV100421415; called by muse, mutect2, varscan2
- ZNF512B | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs771936199, COSV99411659; called by muse, mutect2, varscan2
- ZNF546 | c.785T>C p.V262A | Missense Mutation (SNP) | VAF 67/251 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.048); catalogued as rs368812524, COSV100713496; called by muse, mutect2, varscan2
- ZNF653 | c.1374G>T p.M458I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99542205; called by muse, mutect2
- ZNF675 | c.1553G>A p.S518N | Missense Mutation (SNP) | VAF 93/294 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs879137117, COSV63096759; called by muse, mutect2, varscan2
- ZNF765 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.41); catalogued as COSV101125466, COSV67182357; called by muse, mutect2, varscan2
- ZNF777 | c.1223G>T p.G408V | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV99925238; called by muse, mutect2, varscan2
- ZNF839 | c.583A>G p.K195E (on ENST00000558850 / NM_001267827.1; = p.K311E on NM_018335.5) | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV51757067; called by muse, mutect2, varscan2
- ACVR2A | c.817-2A>T p.X273_splice | Splice Site (SNP) | VAF 36/174 reads (21%) | called by muse, mutect2, varscan2
- ADGRG4 | c.4823dup p.L1608Ffs*76 | Frame Shift Ins (INS) | VAF 212/850 reads (25%) | called by mutect2, pindel, varscan2
- ADGRL1 | c.3772dup p.D1258Gfs*10 (on ENST00000340736 / NM_001008701.3; = p.D1253Gfs*10 on NM_014921.5) | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- AMPD1 | c.2003dup p.L668Ffs*16 | Frame Shift Ins (INS) | VAF 18/100 reads (18%) | called by mutect2, varscan2
- APC | c.4005del p.S1335Rfs*80 | Frame Shift Del (DEL) | VAF 92/314 reads (29%) | called by mutect2, pindel, varscan2
- ARFIP1 | c.642dup p.G215Wfs*3 (on ENST00000353617 / NM_001287432.1; = p.G183Wfs*3 on NM_014447.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 35/145 reads (24%) | called by mutect2, pindel, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 75/375 reads (20%) | called by mutect2, pindel, varscan2
- BMP1 | c.285dup p.S96Qfs*20 | Frame Shift Ins (INS) | VAF 42/88 reads (48%) | called by mutect2, varscan2
- BOD1L1 | c.708del p.K236Nfs*65 | Frame Shift Del (DEL) | VAF 18/106 reads (17%) | called by mutect2, pindel, varscan2
- C5 | c.289A>G p.N97D | Missense Mutation (SNP) | VAF 5/114 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2
- C8B | c.7A>G p.N3D | Missense Mutation (SNP) | VAF 6/161 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.066); called by muse, mutect2
- CA2 | c.63dup p.I22Hfs*11 | Frame Shift Ins (INS) | VAF 29/140 reads (21%) | called by mutect2, pindel, varscan2
- CASP8AP2 | c.1683del p.K561Nfs*2 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel, varscan2
- CBLL1 | c.227dup p.E77* | Frame Shift Ins (INS) | VAF 37/204 reads (18%) | called by mutect2, pindel, varscan2
- CBX5 | c.317dup p.R107Efs*6 | Frame Shift Ins (INS) | VAF 142/578 reads (25%) | called by mutect2, varscan2
- CCDC93 | c.268dup p.I90Nfs*47 | Frame Shift Ins (INS) | VAF 17/91 reads (19%) | called by mutect2, pindel, varscan2
- CCNE2 | c.124dup p.R42Kfs*12 | Frame Shift Ins (INS) | VAF 103/320 reads (32%) | called by mutect2, varscan2
- CCNJL | c.1287dup p.T430Hfs*5 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- CCT8L2 | c.1654del p.I552Sfs*4 | Frame Shift Del (DEL) | VAF 50/173 reads (29%) | called by mutect2, varscan2
- CLSPN | c.3220dup p.E1074Gfs*4 | Frame Shift Ins (INS) | VAF 128/563 reads (23%) | called by mutect2, pindel, varscan2
- CMTR1 | c.177dup p.K60Efs*6 | Frame Shift Ins (INS) | VAF 55/278 reads (20%) | called by mutect2, pindel, varscan2
- ELL | c.805del p.V269Cfs*16 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- EMILIN2 | c.858del p.V287* | Frame Shift Del (DEL) | VAF 33/104 reads (32%) | called by mutect2, pindel, varscan2
- EPS15 | c.464T>C p.L155S | Missense Mutation (SNP) | VAF 15/294 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ESF1 | c.1930del p.R644Dfs*2 | Frame Shift Del (DEL) | VAF 61/356 reads (17%) | called by mutect2, pindel, varscan2
- FAM222B | c.208dup p.Q70Pfs*48 | Frame Shift Ins (INS) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- FANCD2 | c.2774dup p.R926Pfs*6 | Frame Shift Ins (INS) | VAF 37/183 reads (20%) | called by mutect2, pindel, varscan2
- FBN3 | c.730dup p.A244Gfs*7 | Frame Shift Ins (INS) | VAF 15/66 reads (23%) | called by mutect2, pindel, varscan2
- FRMPD4 | c.327dup p.S110Lfs*2 | Frame Shift Ins (INS) | VAF 45/240 reads (19%) | called by mutect2, pindel, varscan2
- FSTL5 | c.45dup p.L16Sfs*16 | Frame Shift Ins (INS) | VAF 38/224 reads (17%) | called by mutect2, varscan2
- GATA4 | c.1220dup p.Q408Tfs*54 | Frame Shift Ins (INS) | VAF 126/362 reads (35%) | called by mutect2, pindel, varscan2
- GOLGA6A | c.740T>A p.M247K | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2
- GRM8 | c.2616dup p.G873Rfs*3 | Frame Shift Ins (INS) | VAF 80/362 reads (22%) | called by mutect2, pindel, varscan2
- H2AC20 | c.101dup p.L34Ffs*78 | Frame Shift Ins (INS) | VAF 21/113 reads (19%) | called by mutect2, pindel, varscan2
- HLA-DOA | c.357dup p.K120Qfs*37 | Frame Shift Ins (INS) | VAF 25/127 reads (20%) | called by mutect2, pindel, varscan2
- HOXA1 | c.226dup p.Q76Pfs*102 | Frame Shift Ins (INS) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- ILF3 | c.1911del p.N638Tfs*29 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | called by mutect2, varscan2
- IP6K2 | c.869del p.F290Sfs*22 | Frame Shift Del (DEL) | VAF 30/109 reads (28%) | called by mutect2, pindel, varscan2
- IQGAP1 | c.2822dup p.N941Kfs*2 | Frame Shift Ins (INS) | VAF 75/306 reads (25%) | called by mutect2, varscan2
- JAZF1 | c.354del p.S119Pfs*47 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- KCTD16 | c.300dup p.P101Sfs*11 | Frame Shift Ins (INS) | VAF 48/198 reads (24%) | called by pindel, varscan2
- KMT2C | c.13940dup p.S4648Vfs*2 | Frame Shift Ins (INS) | VAF 39/170 reads (23%) | called by mutect2, pindel, varscan2
- KMT2C | c.10895dup p.P3633Tfs*19 | Frame Shift Ins (INS) | VAF 50/236 reads (21%) | called by mutect2, pindel, varscan2
- L3MBTL3 | c.171dup p.A58Sfs*64 | Frame Shift Ins (INS) | VAF 35/164 reads (21%) | called by mutect2, pindel, varscan2
- LRP1B | c.9299dup p.N3100Kfs*6 | Frame Shift Ins (INS) | VAF 21/120 reads (18%) | called by mutect2, pindel, varscan2
- LRRC37B | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 8/246 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.34); called by muse, mutect2
- LRRC7 | c.3192dup p.V1065Sfs*5 (on ENST00000651989 / NM_001370785.2; = p.V1032Sfs*5 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 24/98 reads (24%) | called by mutect2, varscan2
- MCUR1 | c.686del p.K229Rfs*3 | Frame Shift Del (DEL) | VAF 104/282 reads (37%) | called by mutect2, pindel, varscan2
- MNDA | c.529dup p.Q177Pfs*48 | Frame Shift Ins (INS) | VAF 112/563 reads (20%) | called by mutect2, pindel, varscan2
- MRPS31 | c.924dup p.K309Efs*8 | Frame Shift Ins (INS) | VAF 64/376 reads (17%) | called by mutect2, pindel, varscan2
- MYCBP2 | c.7418_7420del p.D2473del (on ENST00000357337; = p.D2511del on NM_015057.5) | In Frame Del (DEL) | VAF 84/246 reads (34%) | called by pindel, varscan2
- NCR1 | c.691dup p.W231Lfs*45 | Frame Shift Ins (INS) | VAF 90/441 reads (20%) | called by mutect2, pindel, varscan2
- NFAT5 | c.3182dup p.L1061Ffs*35 | Frame Shift Ins (INS) | VAF 164/727 reads (23%) | called by mutect2, pindel, varscan2
- NUCB2 | c.322dup p.R108Kfs*12 | Frame Shift Ins (INS) | VAF 47/194 reads (24%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.2317dup p.H773Pfs*6 | Frame Shift Ins (INS) | VAF 58/266 reads (22%) | called by pindel, varscan2
- PFKP | c.2130dup p.F711Ifs*5 | Frame Shift Ins (INS) | VAF 30/94 reads (32%) | called by mutect2, varscan2
- PLB1 | c.1987del p.R663Efs*39 | Frame Shift Del (DEL) | VAF 32/149 reads (21%) | called by mutect2, pindel, varscan2
- PLEC | c.13680_13681del p.K4561Afs*3 (on ENST00000322810 / NM_201380.4; = p.K4451Afs*3 on NM_000445.5) | Frame Shift Del (DEL) | VAF 17/42 reads (40%) | called by mutect2, pindel, varscan2
- PSMA4 | c.193del p.I65Ffs*15 | Frame Shift Del (DEL) | VAF 30/180 reads (17%) | called by mutect2, pindel, varscan2
- PTPRK | c.1341dup p.K448Qfs*32 | Frame Shift Ins (INS) | VAF 45/297 reads (15%) | called by mutect2, pindel, varscan2
- RALGPS2 | c.219_220dup p.S74Ffs*28 | Frame Shift Ins (INS) | VAF 19/173 reads (11%) | called by mutect2, pindel, varscan2
- RIT1 | c.483dup p.E162* | Frame Shift Ins (INS) | VAF 94/349 reads (27%) | called by mutect2, varscan2
- RLF | c.5009dup p.T1671Nfs*5 | Frame Shift Ins (INS) | VAF 51/183 reads (28%) | called by mutect2, pindel, varscan2
- RNASEH2B | c.903dup p.G302Wfs*5 | Frame Shift Ins (INS) | VAF 50/137 reads (36%) | called by mutect2, pindel, varscan2
- ROBO1 | c.2265dup p.N756* | Frame Shift Ins (INS) | VAF 25/77 reads (32%) | called by mutect2, varscan2
- SCN9A | c.5790del p.D1931Ifs*31 (on ENST00000303354; = p.D1920Ifs*31 on NM_002977.3) | Frame Shift Del (DEL) | VAF 34/171 reads (20%) | called by mutect2, pindel, varscan2
- SETD2 | c.7657dup p.A2553Gfs*10 | Frame Shift Ins (INS) | VAF 28/117 reads (24%) | called by mutect2, pindel, varscan2
- SLC45A2 | c.527dup p.E177Gfs*63 | Frame Shift Ins (INS) | VAF 64/244 reads (26%) | called by mutect2, pindel, varscan2
- SREK1IP1 | c.253del p.I85Sfs*3 | Frame Shift Del (DEL) | VAF 20/85 reads (24%) | called by mutect2, pindel, varscan2
- SSUH2 | c.372dup p.R125Qfs*116 | Frame Shift Ins (INS) | VAF 16/67 reads (24%) | called by mutect2, pindel, varscan2
- STPG1 | c.23dup p.N8Kfs*2 (on ENST00000337248 / NM_001199013.2; = p.M1? on NM_178122.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 32/136 reads (24%) | called by mutect2, pindel, varscan2
- TOP1 | c.525dup p.P176Tfs*4 | Frame Shift Ins (INS) | VAF 18/83 reads (22%) | called by mutect2, pindel, varscan2
- TRIM67 | c.1472dup p.L491Ffs*21 | Frame Shift Ins (INS) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- UBE3B | c.183dup p.K62* | Frame Shift Ins (INS) | VAF 65/254 reads (26%) | called by mutect2, varscan2
- UBE4B | c.1329_1338+24delinsGCACCAAAGGTAATATGAAATGGATTAACTT p.X443_splice (on ENST00000343090 / NM_001105562.3; = p.X314_splice on NM_006048.5) | Splice Site (DEL) | VAF 10/102 reads (10%) | called by pindel, varscan2*
- VPS13B | c.6215dup p.N2072Kfs*8 | Frame Shift Ins (INS) | VAF 50/339 reads (15%) | called by mutect2, pindel, varscan2
- VPS26A | c.64dup p.E22Gfs*11 | Frame Shift Ins (INS) | VAF 56/220 reads (25%) | called by mutect2, pindel, varscan2
- ZNF518B | c.1400del p.N467Ifs*15 | Frame Shift Del (DEL) | VAF 34/164 reads (21%) | called by mutect2, varscan2
- ZNF831 | c.3054dup p.G1019Rfs*15 | Frame Shift Ins (INS) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- ADAMTS20 | c.4701T>C p.N1567= | Silent (SNP) | VAF 60/219 reads (27%) | catalogued as COSV67130212; called by muse, mutect2, varscan2
- ADH5 | c.861C>T p.G287= | Silent (SNP) | VAF 40/396 reads (10%) | catalogued as rs1422793450, COSV99596288; called by muse, mutect2
- ADHFE1 | c.216T>C p.G72= | Silent (SNP) | VAF 128/723 reads (18%) | catalogued as COSV99397971; called by muse, mutect2, varscan2
- AHCYL1 | c.573T>C p.A191= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV100779608; called by muse, mutect2, varscan2
- AHR | c.2499G>A p.P833= | Silent (SNP) | VAF 126/489 reads (26%) | catalogued as rs763058807, COSV54121800; called by muse, mutect2, varscan2
- ALMS1 | c.10416T>C p.T3472= | Silent (SNP) | VAF 87/324 reads (27%) | catalogued as rs1558699167, COSV52507950; called by muse, mutect2, varscan2
- AMER1 | c.270C>T p.L90= | Silent (SNP) | VAF 74/303 reads (24%) | catalogued as rs148294124, COSV100366611; called by muse, mutect2, varscan2
- ANKRD6 | c.564C>A p.S188= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV60230703; called by muse, mutect2, varscan2
- ARHGAP36 | c.705C>T p.I235= | Silent (SNP) | VAF 67/294 reads (23%) | catalogued as rs775947738, COSV52265870; called by muse, mutect2, varscan2
- ARSH | c.996C>T p.D332= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs143689139, COSV101139915; called by muse, mutect2
- ATG16L1 | c.534A>G p.G178= | Silent (SNP) | VAF 24/268 reads (9%) | catalogued as COSV100731336; called by muse, mutect2
- BMP2 | c.888T>C p.C296= | Silent (SNP) | VAF 54/146 reads (37%) | catalogued as COSV66577537; called by muse, mutect2, varscan2
- CCR6 | c.411T>C p.T137= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV100551135, COSV59476384; called by muse, mutect2, varscan2
- CD226 | c.501G>A p.K167= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV99711250; called by muse, mutect2
- CDCA2 | c.870T>G p.V290= | Silent (SNP) | VAF 53/148 reads (36%) | catalogued as COSV100398956; called by muse, mutect2, varscan2
- CFAP77 | c.789C>T p.Y263= | Silent (SNP) | VAF 13/156 reads (8%) | catalogued as COSV58009996; called by muse, mutect2
- CHEK1 | c.1125A>G p.K375= | Silent (SNP) | VAF 36/174 reads (21%) | catalogued as COSV99629744; called by muse, mutect2, varscan2
- CHST10 | c.849C>T p.H283= | Silent (SNP) | VAF 133/490 reads (27%) | catalogued as rs1311026808, COSV51804956; called by muse, mutect2, varscan2
- CNOT1 | c.4323T>C p.A1441= | Silent (SNP) | VAF 13/224 reads (6%) | catalogued as COSV99800561; called by muse, mutect2
- COL5A1 | c.3594C>T p.G1198= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs146176718; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- COX6B1 | c.147C>T p.G49= | Silent (SNP) | VAF 79/354 reads (22%) | catalogued as rs760843390, COSV55838749; called by muse, mutect2, varscan2
- CPA6 | c.945G>A p.K315= | Silent (SNP) | VAF 18/252 reads (7%) | catalogued as rs149196398, COSV52726794; called by muse, mutect2
- CSMD1 | c.96T>C p.C32= | Silent (SNP) | VAF 31/172 reads (18%) | catalogued as rs1249042418, COSV101222112; called by muse, mutect2, varscan2
- DBX2 | c.435G>A p.P145= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs933265525, COSV60336068; called by muse, mutect2, varscan2
- DNAH7 | c.9588T>C p.I3196= | Silent (SNP) | VAF 22/224 reads (10%) | catalogued as COSV100415993; called by muse, mutect2
- DOCK6 | c.687G>A p.P229= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs770443638, COSV99625974; called by muse, mutect2, varscan2
- DPP10 | c.825C>T p.P275= | Silent (SNP) | VAF 273/560 reads (49%) | catalogued as COSV59680613; called by muse, mutect2, varscan2
- DYSF | c.3606G>A p.T1202= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs139897804; called by muse, mutect2, varscan2
- EBAG9 | c.303T>C p.T101= | Silent (SNP) | VAF 62/302 reads (21%) | catalogued as COSV100520834; called by muse, mutect2, varscan2
- EGR1 | c.714T>C p.P238= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as COSV99525494; called by muse, mutect2, varscan2
- EIF2S3 | c.516A>G p.E172= | Silent (SNP) | VAF 12/389 reads (3%) | catalogued as COSV99450946; called by muse, mutect2
- FBN2 | c.3279C>T p.I1093= | Silent (SNP) | VAF 140/531 reads (26%) | catalogued as rs142809999, COSV52495228, COSV52504788; called by muse, mutect2, varscan2
- FERD3L | c.24C>T p.C8= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs1419170034, COSV51762273; called by muse, mutect2, varscan2
- FFAR2 | c.522C>T p.D174= | Silent (SNP) | VAF 64/243 reads (26%) | catalogued as rs546200557, COSV55832135; called by muse, mutect2, varscan2
- FLNA | c.4362T>G p.S1454= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100774870; called by muse, mutect2, varscan2
- FMR1 | c.1551A>G p.P517= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV54423259; called by muse, mutect2, varscan2
- FOXJ2 | c.1656G>A p.R552= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV99368711; called by muse, mutect2, varscan2
- FRAS1 | c.12015T>C p.N4005= | Silent (SNP) | VAF 7/129 reads (5%) | catalogued as rs878978657, COSV99353570; called by muse, mutect2
- FREM2 | c.3834G>T p.V1278= | Silent (SNP) | VAF 93/445 reads (21%) | catalogued as COSV99749359; called by muse, mutect2, varscan2
- FZD5 | c.1101C>T p.I367= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99776425; called by muse, mutect2, varscan2
- GLYR1 | c.972C>T p.C324= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs775989603, COSV100424365; called by muse, mutect2, varscan2
- GNB1 | c.402C>T p.R134= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as rs560214051, COSV66100588; called by muse, mutect2, varscan2
- GPR179 | c.126C>G p.V42= | Silent (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- GSAP | c.192T>C p.D64= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV99990304; called by muse, mutect2, varscan2
- H4C3 | c.31T>C p.L11= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as rs1412206794, COSV100619491, COSV100619586; called by muse, mutect2, varscan2
- HOXD10 | c.246A>C p.T82= | Silent (SNP) | VAF 25/139 reads (18%) | catalogued as COSV99982846; called by muse, mutect2, varscan2
- ICA1 | c.21T>C p.S7= | Silent (SNP) | VAF 52/247 reads (21%) | catalogued as COSV55578106; called by muse, mutect2, varscan2
- IGKV1D-13 | c.18C>T p.P6= | Silent (SNP) | VAF 13/124 reads (10%) | catalogued as rs571225524; called by mutect2, varscan2
- IGSF3 | c.738C>T p.C246= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs777733228, COSV59589483; called by muse, mutect2, varscan2
- INSM2 | c.738C>A p.P246= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV51880948; called by muse, mutect2, varscan2
- ITIH1 | c.1308C>T p.G436= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV99835393; called by muse, mutect2, varscan2
- KBTBD6 | c.615C>T p.H205= | Silent (SNP) | VAF 46/248 reads (19%) | catalogued as COSV101068810; called by muse, mutect2, varscan2
- KCNH4 | c.2739T>C p.G913= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99237490; called by muse, mutect2, varscan2
- KDM4B | c.522G>A p.T174= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99345959; called by muse, mutect2
- KDM5A | c.897T>C p.C299= | Silent (SNP) | VAF 71/265 reads (27%) | catalogued as COSV101238953; called by muse, mutect2, varscan2
- KMT2D | c.639A>G p.L213= | Silent (SNP) | VAF 73/289 reads (25%) | catalogued as COSV56430082; called by muse, mutect2, varscan2
- LIAS | c.588A>T p.A196= (on ENST00000261434 / NM_001363700.2; = p.A299= on NM_006859.4) | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as COSV99787748; called by muse, varscan2
- LRRC14B | c.915G>A p.P305= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs781079330, COSV52043180, COSV52046244; called by muse, mutect2, varscan2
- LRRC39 | c.252A>G p.Q84= | Silent (SNP) | VAF 50/189 reads (26%) | catalogued as COSV100734501; called by muse, mutect2, varscan2
- MACF1 | c.19572C>T p.S6524= (on ENST00000372915; = p.S4569= on NM_012090.5) | Silent (SNP) | VAF 60/220 reads (27%) | catalogued as rs758368919, COSV57133076; called by muse, mutect2, varscan2
- MED1 | c.4740G>A p.G1580= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV100327938; called by muse, mutect2, varscan2
- MMP14 | c.588C>T p.G196= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs368784954; called by muse, mutect2, varscan2
- MPDZ | c.3048T>C p.S1016= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV59925162; called by muse, mutect2, varscan2
- MPV17L | c.390G>A p.L130= (on ENST00000396385 / NM_001128423.2; = p.D107N on NM_173803.4) | Silent (SNP) | VAF 39/299 reads (13%) | catalogued as COSV99806240; called by muse, mutect2, varscan2
- MRPS27 | c.327C>T p.I109= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as COSV99782327; called by muse, mutect2, varscan2
- MSANTD3 | c.288C>T p.S96= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV58497557; called by muse, mutect2, varscan2
- MYH14 | c.3573G>A p.Q1191= | Silent (SNP) | VAF 18/161 reads (11%) | catalogued as COSV99223277; called by muse, mutect2, varscan2
- MYH9 | c.3912C>T p.S1304= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1419369426, COSV53392784; called by muse, mutect2, varscan2
- NCOA6 | c.5259T>C p.V1753= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV100750147; called by muse, mutect2, varscan2
- NIPBL | c.3270A>G p.S1090= | Silent (SNP) | VAF 39/154 reads (25%) | catalogued as COSV56959925; called by muse, mutect2, varscan2
- NLRP14 | c.1866T>C p.L622= | Silent (SNP) | VAF 60/241 reads (25%) | catalogued as COSV55065429; called by muse, mutect2, varscan2
- NR1D2 | c.810G>A p.E270= | Silent (SNP) | VAF 30/161 reads (19%) | catalogued as rs1195644235, COSV100437506; called by muse, mutect2, varscan2
- NUP205 | c.1812G>A p.T604= | Silent (SNP) | VAF 52/193 reads (27%) | catalogued as rs772002920, COSV99607195; called by muse, mutect2, varscan2
- P3H3 | c.834C>G p.G278= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99301409; called by muse, mutect2
- PARP4 | c.4269G>A p.R1423= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- PCDHB3 | c.1659C>T p.D553= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV99165672; called by muse, mutect2, varscan2
- PCNX3 | c.2388C>T p.G796= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1458883729, COSV100856135; called by muse, mutect2
- PDZD2 | c.2475A>G p.E825= | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as COSV99225603; called by muse, mutect2
- PLXNA1 | c.1083G>A p.T361= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs374766048; called by muse, mutect2, varscan2
- PPP3CA | c.534T>C p.C178= | Silent (SNP) | VAF 54/182 reads (30%) | catalogued as COSV100547827; called by muse, mutect2, varscan2
- PROM1 | c.1623T>C p.Y541= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV101477100; called by muse, mutect2
- PYGO2 | c.522C>T p.N174= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs773146776, COSV100868958; called by muse, mutect2, varscan2
- QRSL1 | c.402A>G p.V134= | Silent (SNP) | VAF 14/161 reads (9%) | catalogued as COSV64687321; called by muse, mutect2
- RAD51AP2 | c.2313T>C p.H771= | Silent (SNP) | VAF 59/201 reads (29%) | catalogued as COSV67587811; called by muse, varscan2
- RASSF4 | c.105T>C p.H35= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as rs535440293, COSV100024439; called by muse, mutect2, varscan2
- RBM15 | c.1509G>A p.A503= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs143285609; called by muse, mutect2, varscan2
- RC3H2 | c.2742A>C p.T914= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV61799555; called by muse, mutect2, varscan2
- RGS3 | c.393G>A p.T131= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as rs745805685, COSV58280299; called by muse, mutect2, varscan2
- RIF1 | c.2334C>A p.P778= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV99690783; called by muse, mutect2, varscan2
- RNF111 | c.357G>A p.R119= | Silent (SNP) | VAF 91/466 reads (20%) | catalogued as COSV100789103; called by muse, mutect2, varscan2
- RP1L1 | c.3948A>G p.Q1316= | Silent (SNP) | VAF 14/248 reads (6%) | catalogued as COSV101223381; called by muse, mutect2
- SCAP | c.273T>C p.A91= | Silent (SNP) | VAF 32/126 reads (25%) | catalogued as COSV99652978; called by muse, mutect2, varscan2
- SCMH1 | c.1740C>T p.R580= (on ENST00000326197 / NM_001031694.2; = p.R511= on NM_012236.4) | Silent (SNP) | VAF 49/147 reads (33%) | catalogued as rs778375263, COSV100401922; called by muse, mutect2, varscan2
- SDCCAG8 | c.471C>T p.N157= | Silent (SNP) | VAF 106/388 reads (27%) | catalogued as rs769881390, COSV59410929; called by muse, mutect2, varscan2
- SEL1L3 | c.2490G>A p.A830= | Silent (SNP) | VAF 143/615 reads (23%) | catalogued as rs751256965, COSV53537696, COSV53542065; called by muse, mutect2, varscan2
- SERINC4 | c.960T>C p.N320= | Silent (SNP) | VAF 11/272 reads (4%) | catalogued as COSV99988514; called by muse, mutect2
- SGTB | c.213T>C p.V71= | Silent (SNP) | VAF 55/183 reads (30%) | catalogued as COSV101121605; called by muse, mutect2, varscan2
- SHROOM2 | c.186C>T p.A62= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as rs374833426, COSV66605877, COSV66610933; called by muse, mutect2, varscan2
- SKIV2L | c.3187C>A p.R1063= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as CM166716, COSV61713303; called by muse, mutect2, varscan2
- SLC23A1 | c.1047A>G p.P349= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100812034; called by muse, mutect2, varscan2
- SLC25A32 | c.822C>T p.G274= | Silent (SNP) | VAF 151/342 reads (44%) | catalogued as rs191949047, COSV52567468; called by muse, mutect2, varscan2
- SLC38A3 | c.1086T>C p.F362= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV101309957; called by muse, mutect2, varscan2
- SLCO4C1 | c.570A>G p.S190= | Silent (SNP) | VAF 39/129 reads (30%) | catalogued as COSV100195272; called by muse, mutect2, varscan2
- SLCO5A1 | c.2196G>A p.T732= | Silent (SNP) | VAF 36/499 reads (7%) | catalogued as rs201047618, COSV52659942; called by muse, mutect2
- SPATA31A1 | c.3642A>G p.G1214= | Silent (SNP) | VAF 128/660 reads (19%) | called by muse, mutect2, varscan2
- SPG11 | c.771T>C p.S257= | Silent (SNP) | VAF 43/227 reads (19%) | catalogued as COSV99969017; called by muse, varscan2
- SPRED1 | c.945T>C p.P315= | Silent (SNP) | VAF 11/239 reads (5%) | catalogued as COSV100136252, COSV54438318; called by muse, mutect2
- SYN3 | c.1581G>A p.K527= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV100249384; called by muse, mutect2, varscan2
- SYT10 | c.261A>G p.K87= | Silent (SNP) | VAF 42/185 reads (23%) | catalogued as COSV57339441; called by muse, mutect2, varscan2
- TAS2R31 | c.918T>G p.P306= | Silent (SNP) | VAF 96/910 reads (11%) | catalogued as COSV101115070; called by muse, varscan2
- TET3 | c.750C>T p.S250= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV99996442, COSV99996500; called by muse, mutect2, varscan2
- TG | c.7413C>A p.A2471= | Silent (SNP) | VAF 24/486 reads (5%) | catalogued as COSV99601731; called by muse, mutect2
- TGFBRAP1 | c.72C>T p.R24= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs752744698, COSV51514271; called by muse, mutect2, varscan2
- THBS2 | c.2052C>T p.Y684= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs776371244, COSV64680867; called by muse, mutect2, varscan2
- TMCO6 | c.1248C>T p.C416= | Silent (SNP) | VAF 118/527 reads (22%) | catalogued as rs1221509723, COSV99347231; called by muse, mutect2, varscan2
- TNC | c.702A>C p.G234= | Silent (SNP) | VAF 9/103 reads (9%) | catalogued as COSV100405975; called by muse, mutect2
- TNXB | c.2679G>A p.T893= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs1349120818, COSV64477575; called by muse, mutect2, varscan2
- TPD52L2 | c.69G>A p.T23= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as rs929634458, COSV53863155; called by muse, mutect2, varscan2
- TPR | c.1020A>G p.K340= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as rs374064614; called by muse, mutect2, varscan2
- TRAFD1 | c.1131G>A p.L377= | Silent (SNP) | VAF 15/148 reads (10%) | catalogued as COSV99986915; called by muse, mutect2
- TRAK2 | c.1593T>A p.L531= | Silent (SNP) | VAF 23/212 reads (11%) | catalogued as COSV100216908; called by muse, mutect2, varscan2
- TRPV5 | c.1041C>T p.C347= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as rs55754004, COSV54690459; called by muse, mutect2, varscan2
- TSHZ2 | c.1938C>T p.T646= | Silent (SNP) | VAF 66/340 reads (19%) | catalogued as rs536653149, COSV100296331; called by muse, mutect2, varscan2
- TUBG1 | c.1009T>C p.L337= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs751960976, COSV52220903; called by muse, mutect2
- UPK1B | c.495A>G p.P165= | Silent (SNP) | VAF 40/151 reads (26%) | catalogued as COSV99953676; called by muse, mutect2, varscan2
- VAV2 | c.2160C>T p.I720= (on ENST00000371850 / NM_001134398.2; = p.I710= on NM_003371.4) | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as COSV100895955; called by muse, varscan2
- WDR49 | c.870G>A p.A290= (on ENST00000308378 / NM_001366158.1; = p.A631= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as rs200046064, COSV57706589; called by muse, mutect2, varscan2
- ZDHHC20 | c.810C>A p.V270= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV57185350; called by muse, mutect2, varscan2
- ZNF148 | c.1305A>G p.L435= | Silent (SNP) | VAF 43/283 reads (15%) | catalogued as COSV100642134; called by muse, mutect2, varscan2
- ZNF292 | c.4338A>G p.A1446= | Silent (SNP) | VAF 114/443 reads (26%) | catalogued as COSV100370641; called by muse, mutect2, varscan2
- ZNF480 | c.858G>A p.P286= | Silent (SNP) | VAF 53/178 reads (30%) | catalogued as rs146275422; called by muse, mutect2, varscan2
- ZNF530 | c.576T>C p.I192= | Silent (SNP) | VAF 89/295 reads (30%) | catalogued as rs1471043798, COSV100252647; called by muse, mutect2, varscan2
- ZNF678 | c.906T>C p.F302= | Silent (SNP) | VAF 25/302 reads (8%) | catalogued as COSV100652847; called by muse, mutect2
- AL132655.6 | chr20:58840356 T>A | 5'Flank (SNP) | VAF 11/53 reads (21%) | catalogued as rs747330417, COSV100006961; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852595 del T | 3'Flank (DEL) | VAF 10/37 reads (27%) | called by mutect2, pindel, varscan2
- BRD9 | c.401-15del | Intron (DEL) | VAF 23/68 reads (34%) | catalogued as rs747777302, COSV51319227; called by mutect2, varscan2
- CCDC28A | c.-107T>C | 5'UTR (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100236554; called by muse, mutect2, varscan2
- COLEC11 | c.203-11468T>C | Intron (SNP) | VAF 50/347 reads (14%) | catalogued as COSV99363387; called by muse, mutect2, varscan2
- COX15 | c.*1155A>G | 3'UTR (SNP) | VAF 31/270 reads (11%) | catalogued as COSV99187278; called by muse, mutect2, varscan2
- HMGB1P1 | n.302C>T | RNA (SNP) | VAF 18/532 reads (3%) | called by muse, mutect2
- IMPDH1 | chr7:128409291 A>G | 5'Flank (SNP) | VAF 6/26 reads (23%) | catalogued as COSV58315713; called by muse, mutect2
- KMT2C | c.11670+987C>T | Intron (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100073624; called by muse, mutect2, varscan2
- KNOP1P1 | n.249del | RNA (DEL) | VAF 26/135 reads (19%) | catalogued as rs762636138; called by mutect2, varscan2
- LPAL2 | n.200A>G | RNA (SNP) | VAF 125/588 reads (21%) | called by muse, mutect2, varscan2
- MIR365B | n.71T>C | RNA (SNP) | VAF 47/174 reads (27%) | called by muse, mutect2, varscan2
- MIR518F | n.58C>T | RNA (SNP) | VAF 70/376 reads (19%) | catalogued as rs557837040; called by muse, mutect2, varscan2
- P3H1 | c.2055+28A>G | Intron (SNP) | VAF 25/91 reads (27%) | catalogued as COSV52532996; called by muse, mutect2, varscan2
- RBM44 | c.-98-2726del | Intron (DEL) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- VPS13D | c.13035+174C>T | Intron (SNP) | VAF 21/206 reads (10%) | catalogued as rs199796890, COSV99167373; called by muse, mutect2, varscan2
- ZNF618 | c.755-533C>T | Intron (SNP) | VAF 25/147 reads (17%) | catalogued as COSV55920001; called by muse, mutect2, varscan2
